Somatic mutation profile of tumor specimen TCGA-61-2003-01A (aliquot TCGA-61-2003-01A-01W-0722-08) from TCGA case TCGA-61-2003, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.7 years (19,605 days).
Specimen TCGA-61-2003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb9fa14a-be1b-428e-b00b-6585783f484d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2003-10A (Blood Derived Normal), aliquot TCGA-61-2003-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c50cc40c-14e6-4407-8e8c-1b9fd1b0412f

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587779491, CM1412691, CM1512460, COSV100482433; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKZF1 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs1292671661, COSV55477584; called by muse, mutect2, varscan2
- ARL5B | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101040230; called by muse, mutect2
- ATP12A | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as COSV54519507; called by muse, mutect2, varscan2
- ATRNL1 | c.2154A>T p.K718N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100744164; called by muse, mutect2
- BCORL1 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54397937; called by muse, varscan2
- CNTN1 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61642397; called by muse, mutect2, varscan2
- CYFIP2 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV59044778; called by muse, mutect2, varscan2
- ESCO2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV59417092; called by muse, mutect2
- FBXO38 | c.2297G>C p.G766A | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.158); catalogued as COSV99693100; called by muse, mutect2
- FHL5 | c.136A>C p.K46Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV58738930; called by muse, mutect2, varscan2
- FMN2 | c.4713G>T p.M1571I | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV100142618; called by muse, mutect2
- GRIP1 | c.1356G>T p.L452F (on ENST00000359742 / NM_001379345.1; = p.L400F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV54017678; called by muse, mutect2
- GTF2E1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 83/609 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781417478, COSV52205302; called by muse, mutect2, varscan2
- H4C4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.08); catalogued as COSV61591699; called by muse, mutect2, varscan2
- HHIPL2 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596578, COSV58565207; called by muse, mutect2
- IKZF3 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53104365; called by muse, mutect2, varscan2
- IKZF3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1260075009, COSV99499214; called by muse, varscan2
- LUC7L3 | c.604G>C p.G202R | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536717; called by muse, mutect2
- MYH7B | c.582A>G p.I194M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53422593; called by muse, mutect2, varscan2
- NELFCD | c.961G>A p.V321I (on ENST00000602795; = p.V303I on NM_198976.4) | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); catalogued as rs375888011; called by muse, mutect2, varscan2
- NUDT5 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58502182; called by muse, mutect2, varscan2
- OR4C13 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 30/536 reads (6%) | catalogued as rs372081598; called by muse, mutect2
- PEBP1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV54336640; called by muse, mutect2, varscan2
- PHF3 | c.4949G>C p.R1650T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100012790, COSV100012868; called by muse, mutect2
- PMEL | c.24C>G p.C8W | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57186992; called by muse, mutect2, varscan2
- QRICH1 | c.834T>G p.S278R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100676638; called by muse, mutect2, varscan2
- RASGRP3 | c.1354T>C p.F452L (on ENST00000402538 / NM_001349975.2; = p.F451L on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67823411; called by muse, mutect2, varscan2
- RELB | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.092); catalogued as COSV55511694; called by muse, mutect2, varscan2
- RRP12 | c.2105C>A p.A702E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100212874; called by muse, mutect2
- RUFY2 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56260302; called by muse, mutect2, varscan2
- RWDD2B | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99725503; called by muse, mutect2
- SCLT1 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55409411; called by muse, mutect2, varscan2
- SLC12A1 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100372188; called by muse, mutect2
- SLC17A9 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs772910639, COSV64846708; called by muse, mutect2, varscan2
- SPATA5 | c.1874C>A p.S625Y | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99914707; called by muse, mutect2
- TMEM38A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs778995490, COSV51818316; called by muse, mutect2, varscan2
- TMEM63A | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV100834252; called by muse, mutect2
- TRMT1L | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV100834558; called by muse, mutect2
- TTN | c.26738G>T p.G8913V (on ENST00000591111; = p.G7986V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | PolyPhen benign (0.204); catalogued as COSV100593766; called by muse, mutect2
- ZNF304 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99988385; called by muse, mutect2
- ZNF644 | c.596C>A p.S199* | Nonsense Mutation (SNP) | VAF 130/695 reads (19%) | catalogued as COSV100494263; called by muse, mutect2, varscan2
- ZNF644 | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 127/697 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100494264; called by muse, mutect2, varscan2
- AL121899.2 | c.1247_1272del p.R416Hfs*42 | Frame Shift Del (DEL) | VAF 108/352 reads (31%) | called by mutect2, pindel
- FBXO34 | c.47dup p.E17Gfs*19 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- FES | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.399); called by mutect2, varscan2
- MAP3K14 | c.2673_2674insTCC p.S892dup | In Frame Ins (INS) | VAF 20/54 reads (37%) | called by pindel, varscan2
- SERPING1 | c.1461del p.K487Nfs*89 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- STOX1 | c.2878C>T p.Q960* | Nonsense Mutation (SNP) | VAF 19/197 reads (10%) | called by mutect2, varscan2
- VN1R5 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 278/566 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDHD1 | c.201G>A p.Q67= (on ENST00000323669; = p.Q298= on NM_030637.3) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1441856813, COSV60360651, COSV60361039; called by muse, mutect2, varscan2
- FOCAD | c.4623G>T p.L1541= | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as COSV100620026; called by muse, mutect2
- HHIPL2 | c.1233C>T p.P411= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as rs979592834, COSV100596576; called by muse, mutect2
- HMCN1 | c.9777T>C p.L3259= | Silent (SNP) | VAF 25/266 reads (9%) | catalogued as COSV54918134; called by muse, mutect2
- ITPRIPL1 | c.1482C>G p.L494= (on ENST00000439118 / NM_001008949.3; = p.L502= on NM_178495.6) | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100742156; called by muse, mutect2, varscan2
- LRRC40 | c.1716G>A p.L572= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100918696; called by muse, mutect2
- MRTFA | c.453G>A p.E151= | Silent (SNP) | VAF 40/423 reads (9%) | catalogued as COSV62934873; called by muse, mutect2
- NAT1 | c.570C>T p.Y190= | Silent (SNP) | VAF 34/281 reads (12%) | catalogued as rs1212248879, COSV100306437; called by mutect2, varscan2
- PDGFRA | c.2121C>A p.I707= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV57270820; called by muse, varscan2
- PJVK | c.804T>G p.L268= | Silent (SNP) | VAF 15/197 reads (8%) | catalogued as COSV99247434; called by muse, mutect2
- RYR1 | c.12555G>A p.A4185= | Silent (SNP) | VAF 22/336 reads (7%) | catalogued as rs1442355076, COSV62108558; called by muse, mutect2
- TAAR2 | c.540C>T p.F180= (on ENST00000367931 / NM_001033080.1; = p.F135= on NM_014626.3) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV51578458; called by muse, mutect2, varscan2
- TP53BP2 | c.1779C>T p.P593= (on ENST00000343537 / NM_001031685.3; = p.P464= on NM_005426.2) | Silent (SNP) | VAF 74/760 reads (10%) | catalogued as rs776132793, COSV100636893, COSV59070547; called by muse, mutect2
- UNC79 | c.3807C>T p.D1269= (on ENST00000393151 / NM_001346218.2; = p.D1092= on NM_020818.5) | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as rs567253162, COSV56398104; called by muse, mutect2, varscan2
- CACNB2 | c.214-849G>A | Intron (SNP) | VAF 16/224 reads (7%) | catalogued as COSV99993014; called by muse, mutect2
- VAV3 | c.322-5978A>T | Intron (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100579101; called by muse, mutect2
